TCGA case TCGA-E3-A3DZ — Thyroid Carcinoma (TCGA-THCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Thyroid gland; Tissue source site: Roswell Park. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/59e47734-96de-4328-aca7-e9423dda9c52

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 55 years; Vital status: Alive.

Diagnoses (1)
1. Papillary carcinoma, follicular variant: ICD-O-3 morphology code: 8340/3; ICD-10 code: C73; Tissue or organ of origin: Thyroid gland; Site of resection or biopsy: Thyroid gland; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 55.4 years (20,251 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage III; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,436 days (3.9 years); Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 1; Measurement unit: Centimeters; Tumor depth measurement: 3; Tumor length measurement: 4.5; Tumor width measurement: 5.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Levothyroxine Sodium; Days to treatment start: 25 days; Days to treatment end: 25 days.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Liothyronine Sodium; Days to treatment start: 30 days; Days to treatment end: 56 days.
   Treatment given: Treatment type: Radiation, Systemic; Days to treatment start: 56 days; Days to treatment end: 56 days; Treatment dose: 150 mCi; Treatment outcome: Complete Response; Number of fractions: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Levothyroxine Sodium; Days to treatment start: 59 days; Treatment outcome: Treatment Ongoing.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Treatment dose: 150; Pretreatment: rhTSH.
   Treatment given: Treatment type: I-131 Radiation Therapy; Treatment intent type: Adjuvant; Prescribed dose: 150; Pretreatment: rhTSH; Timepoint category: First Treatment.
   Recorded as not given: adjuvant Radiation, External Beam.

Follow-up (4 entries)
- Days to follow up: 367 days (1.0 years); Disease response: Tumor Free.
- Imaging type: CT Scan; Imaging anatomic site: Lymph Node; Timepoint: Preoperative.
- Disease response: Complete Response; Timepoint: Within 3 Months of Surgery.
- Follow-up contact recording only the day: day 1,436.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Risk factors: Lymphoid Hyperplasia.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-E3-A3DZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 260 mg.
  Slide TCGA-E3-A3DZ-01A-01-TSA: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 95; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-E3-A3DZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-E3-A3DZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; History thyroid disease other: lymphoid hyperplasia; History radiation exposure: No; Submitted tumor site: Thyroid; Histologic diagnosis: Thyroid Papillary Carcinoma - Follicular (>= 99% follicular patterned); Laterality: Right lobe; Lymph nodes preop imaging: Yes; Lymph nodes examined: Yes; Genotypic analysis detected: No.
- Neoplasm dimension: Tumor size width: 3.
- Lymph node preoperative assessment diagnostic imaging types: Lymph nodes preop imaging type: CT without contrast.
- Follow-up form 1: Lost to follow-up: No; Tumor status: Tumor free; I 131 radiation first treatment method: rhTSH; Radiation therapy xrt method prep: Patient Did Not Receive External Radiation Therapy; Clinical status within 3 mths surgery: No imaging evidence of disease; New tumor event diagnosis indicator: No.
- Drug treatment 1: Pharmaceutical therapy drug name: Levothroid.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytomel.
- Drug treatment 3: Pharmaceutical therapy drug name: Synthroid.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,436 days; disease-specific survival: no event (censored), 1,436 days; disease-free interval: no event (censored), 1,436 days; progression-free interval: no event (censored), 1,436 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-E3-A3DZ-01A-11D-A20A-01): tumor purity 0.77, ploidy 1.99, whole-genome doublings 0.
